Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4847, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4847-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, LAPAROSCOPIC RADICAL NEPHRECTOMY—

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR AND FOCAL GRANULAR CELL) TYPE, FUHRMAN NUCLEAR GRADE III OF IV, 3.6 CM IN MAXIMUM DIMENSION (see comment).
- B. CARCINOMA IS PRESENT IN MID TO UPPER POLE OF THE KIDNEY AND IS CONFINED TO KIDNEY WITHOUT INVASION THROUGH THE RENAL CAPSULE NOR INVOLVEMENT OF THE RENAL SINUS.
- C. NO GROSS INVASION OF THE RENAL VEIN IS IDENTIFIED.
- D. PROBABLE NON-OCCLUSIVE CARCINOMATOUS THROMBUS IN AN INTERLOBAR RENAL VEIN (slide G).
- E. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- F. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- G. NO ADRENAL GLAND IS SUBMITTED.
- H. PATHOLOGIC STAGE: pT3 NX M1 (see comment).
- I. TNM HISTOLOGIC GRADE = G3.

COMMENT:

There are foci of Fuhrman nuclear grade III renal cell carcinoma present on several histologic sections (slides B, E, and F). The largest focus measures 1.2 cm and is distinctly different from the surrounding lower grade carcinoma, suggesting the possibility of focal dedifferentiation. No sarcomatoid carcinoma is identified.

There is an aggregate of renal cell carcinoma within a space which is partially surrounded by a fibromuscular wall. The space is lined by flattened cells, which are immunoreactive for CD31 (endothelial cell marker), suggesting an interlobar renal vein (slide G). This focus is interpreted to represent a probable non-occlusive carcinomatous thrombus. There is no grossly visible thrombus or evidence of involvement of the main renal vein. Based on AJCC staging criteria, a tumor thrombus in a major renal vein is a criterion for a pathologic stage T3 tumor. We are also aware that this patient has a renal cell carcinoma metastasis in the right humerus, confirmed histologically. Therefore, the assigned pathologic M stage is M1.

Source: NCI Genomic Data Commons file d8bfd63c-a1bb-49ff-a420-3d99c2348b52 (TCGA-B0-4847.63F55F7F-5F7E-41D8-9A95-B3F552574D02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).